MMRF case MMRF_2622 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3c6ff74a-c8d3-4002-8b52-0ce1fb3937e0

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 59.7 years (21,814 days); ISS stage: II; Days to last known disease status: 535 days (1.5 years); Days to last follow up: 535 days (1.5 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 53 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 205 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 197 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 205 days; Days to treatment end: 288 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 288 days; Days to treatment end: 316 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 337 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 185 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 4.81 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 3.9 µg/mL; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 9.61 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 99 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 5.06 mmol/L; C-Reactive Protein 0.08 mg/dL.
- Day 92 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.14 mg/dL; Lactate Dehydrogenase 4.33 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6.2 g/dL; Glucose 6.22 mmol/L.
- Day 183 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.99 mg/dL; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.92 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 6.11 mmol/L.
- Day 260 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.33 mg/dL; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 69 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 5.28 mmol/L.
- Day 337 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 78 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 3.14 mmol/L.
- Day 445 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.97 mg/dL; Immunoglobulin G 9.79 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.33 g/L; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 65 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 3.69 mmol/L.
- Day 535 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 9.69 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.33 g/L; Lactate Dehydrogenase 2.05 µkat/L; Hemoglobin 9.36 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 52 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 4.79 mmol/L.

Other clinical attributes
- Day -7: Weight: 85 kg; Height: 185 cm.

Family history
- Relative with cancer history: yes; Relationship type: Paternal Grandfather; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2622_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_2622_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
